Somatic mutation profile of tumor specimen MMRF_2292_1_BM_CD138pos (aliquot MMRF_2292_1_BM_CD138pos_T1_KHS5U_L09556) from MMRF case MMRF_2292, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 74.0 years (27,027 days).
Specimen MMRF_2292_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 173ded2a-d45a-4d67-9d43-69fbf2a3e239.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2292_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2292_1_PB_Whole_C2_KHS5U_L09557; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/46377401-366e-4a43-a332-1e745bf76faf

The open-access MAF lists 126 somatic variants for this specimen: 50 protein-altering or splice-affecting, 19 silent, 57 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, 3'UTR 27, Intron 21, Silent 19, 5'UTR 4, Frame Shift Del 3, Frame Shift Ins 3, Nonsense Mutation 2, RNA 2, 5'Flank 2, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADARB2 | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (0.93); PolyPhen benign (0.013); catalogued as rs990745054, COSV67229363; called by muse, mutect2, varscan2
- ATG9B | c.2053T>C p.W685R | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1457253689; called by muse, mutect2, varscan2
- CARMIL2 | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs755572102; called by muse, mutect2, varscan2
- COL11A2 | c.763C>T p.L255F | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100553923; called by muse, mutect2
- CRACD | c.2728C>T p.R910W | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV99949024; called by muse, varscan2
- FAM170A | c.575A>T p.K192I | Missense Mutation (SNP) | VAF 51/167 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV58925097; called by muse, mutect2, varscan2
- FECH | c.892C>T p.R298* | Nonsense Mutation (SNP) | VAF 24/65 reads (37%) | catalogued as HM030040, COSV50490669; called by muse, mutect2, varscan2
- HSPA12A | c.460G>A p.D154N | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.053); catalogued as rs880002475; called by muse, mutect2, varscan2
- IGHJ5 | c.26G>C p.G9A | Missense Mutation (SNP) | VAF 18/20 reads (90%) | PolyPhen possibly damaging (0.489); catalogued as rs377076784; called by muse, varscan2
- IGLV3-1 | c.187G>C p.V63L | Missense Mutation (SNP) | VAF 39/44 reads (89%) | SIFT tolerated (0.2); PolyPhen benign (0.027); catalogued as rs190667156; called by muse, mutect2, varscan2
- JPH3 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 55/160 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.177); catalogued as rs772600210, COSV52467539; called by muse, mutect2, varscan2
- KLHL29 | c.850C>A p.P284T | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.001); catalogued as rs1442031580; called by muse, mutect2, varscan2
- NTRK3 | c.1192G>C p.E398Q | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.37); PolyPhen benign (0.028); catalogued as COSV58114623, COSV58142385; called by muse, mutect2, varscan2
- PCDHA11 | c.1864C>T p.R622C | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.287); catalogued as rs782808360, COSV56484261; called by muse, mutect2, varscan2
- SIPA1L2 | c.2111A>G p.N704S | Missense Mutation (SNP) | VAF 9/144 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53394375; called by muse, mutect2
- SPTBN4 | c.1387G>A p.A463T | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as rs544695151, COSV58958876; called by muse, mutect2, varscan2
- STAT4 | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.175); catalogued as COSV100636153, COSV104422239; called by muse, mutect2, varscan2
- TREM1 | c.599+1G>T p.X200_splice | Splice Site (SNP) | VAF 22/61 reads (36%) | catalogued as rs1177189732; called by muse, mutect2, varscan2
- USP21 | c.22C>T p.R8C | Missense Mutation (SNP) | VAF 23/421 reads (5%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.63); catalogued as rs780961535, COSV57091564; called by muse, mutect2
- ACTR6 | c.66G>C p.V22= | Splice Region (SNP) | VAF 72/196 reads (37%) | called by muse, mutect2, varscan2
- ADAMTSL2 | c.1852G>A p.A618T | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT tolerated (0.99); PolyPhen benign (0.023); called by muse, mutect2
- AMOTL2 | c.466_467insT p.R156Lfs*5 | Frame Shift Ins (INS) | VAF 49/99 reads (49%) | called by mutect2, pindel*, varscan2*
- ANKRD2 | c.586A>G p.I196V | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.429); called by muse, mutect2
- ATM | c.1685dup p.N562Kfs*4 | Frame Shift Ins (INS) | VAF 25/72 reads (35%) | called by mutect2, pindel, varscan2
- BIRC6 | c.4151T>C p.F1384S | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- BMP5 | c.78A>T p.K26N | Missense Mutation (SNP) | VAF 205/509 reads (40%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2
- C15orf40 | c.41_54del p.T14Rfs*12 | Frame Shift Del (DEL) | VAF 28/49 reads (57%) | called by mutect2, pindel, varscan2
- CAD | c.2438T>A p.V813E | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.377); called by muse, mutect2, varscan2
- CAMSAP2 | c.1085C>T p.P362L (on ENST00000236925 / NM_001297707.2; = p.P351L on NM_203459.3) | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CCDC175 | c.339T>G p.I113M | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- CYP21A2 | c.66G>C p.W22C | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- DCHS2 | c.326A>T p.D109V | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DSC1 | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FAM193A | c.1189T>C p.S397P | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- GOLGA4 | c.90_112del p.T31Dfs*9 | Frame Shift Del (DEL) | VAF 18/183 reads (10%) | called by mutect2, pindel
- KCNIP4 | c.572T>C p.M191T | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- KERA | c.943T>A p.S315T | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2
- MUC5B | c.3425G>A p.C1142Y | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NEURL4 | c.4559A>G p.Y1520C | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by mutect2, varscan2
- NFKB2 | c.1916A>G p.H639R | Missense Mutation (SNP) | VAF 24/25 reads (96%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- NUP205 | c.1590T>A p.C530* | Nonsense Mutation (SNP) | VAF 35/133 reads (26%) | called by muse, mutect2, varscan2
- OR6C74 | c.680C>T p.P227L | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- OR9K2 | c.965A>G p.E322G (on ENST00000305377; = p.E300G on NM_001005243.1) | Missense Mutation (SNP) | VAF 67/178 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- PRDM1 | c.2161dup p.E721Gfs*8 | Frame Shift Ins (INS) | VAF 20/130 reads (15%) | called by pindel, varscan2
- PRDM1 | c.2178_2179del p.N727* | Frame Shift Del (DEL) | VAF 77/158 reads (49%) | called by pindel, varscan2
- RPL13 | c.311A>G p.N104S | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- SP100 | c.2513G>C p.R838P | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TBCC | c.190T>G p.F64V | Missense Mutation (SNP) | VAF 67/171 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- TNC | c.1441G>A p.V481M | Missense Mutation (SNP) | VAF 50/202 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZDHHC8 | c.1531C>T p.P511S | Missense Mutation (SNP) | VAF 42/165 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- CCDC113 | c.855T>C p.L285= | Silent (SNP) | VAF 26/77 reads (34%) | called by muse, mutect2, varscan2
- ENPP2 | c.387C>T p.D129= | Silent (SNP) | VAF 20/44 reads (45%) | called by muse, mutect2, varscan2
- FAT4 | c.144G>A p.V48= | Silent (SNP) | VAF 7/140 reads (5%) | catalogued as rs1396893351; called by muse, mutect2
- FBLN2 | c.2034G>A p.P678= | Silent (SNP) | VAF 21/78 reads (27%) | catalogued as rs765895222, COSV55482699; called by muse, mutect2, varscan2
- IGHV2-70 | c.249T>G p.S83= | Silent (SNP) | VAF 36/100 reads (36%) | catalogued as rs769803427; called by muse, varscan2
- IGHV2-70 | c.81T>G p.G27= | Silent (SNP) | VAF 40/94 reads (43%) | catalogued as rs530772710; called by muse, mutect2, varscan2
- IGLV4-60 | c.138C>T p.S46= | Silent (SNP) | VAF 62/119 reads (52%) | catalogued as rs551751107; called by muse, mutect2, varscan2
- IGLV6-57 | c.60T>C p.N20= | Silent (SNP) | VAF 66/144 reads (46%) | catalogued as rs763692154; called by muse, varscan2
- IGSF11 | c.540G>A p.K180= (on ENST00000393775 / NM_001015887.3; = p.K179= on NM_152538.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/17 reads (41%) | called by muse, mutect2
- MAPK8IP1 | c.1857G>A p.K619= | Silent (SNP) | VAF 28/138 reads (20%) | catalogued as rs758962920; called by muse, mutect2, varscan2
- MUC16 | c.18960A>T p.S6320= | Silent (SNP) | VAF 53/165 reads (32%) | called by muse, varscan2
- NRK | c.24G>A p.R8= | Silent (SNP) | VAF 115/129 reads (89%) | called by muse, mutect2, varscan2
- NXF3 | c.990C>T p.T330= | Silent (SNP) | VAF 12/64 reads (19%) | called by muse, mutect2, varscan2
- OR10J1 | c.138G>C p.V46= | Silent (SNP) | VAF 183/289 reads (63%) | called by muse, mutect2, varscan2
- PCSK4 | c.1215G>A p.A405= | Silent (SNP) | VAF 11/26 reads (42%) | called by muse, mutect2, varscan2
- RIMS2 | c.2985A>C p.P995= (on ENST00000666250 / NM_001348490.2; = p.P803= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 54/104 reads (52%) | called by muse, mutect2, varscan2
- SETD3 | c.355T>C p.L119= | Silent (SNP) | VAF 9/76 reads (12%) | called by muse, mutect2, varscan2
- TMEM184A | c.156C>T p.S52= | Silent (SNP) | VAF 25/56 reads (45%) | catalogued as rs777115164; called by muse, mutect2, varscan2
- XIRP1 | c.2718A>G p.A906= | Silent (SNP) | VAF 37/144 reads (26%) | called by muse, mutect2, varscan2
- AC020688.1 | n.564C>T | RNA (SNP) | VAF 32/73 reads (44%) | catalogued as rs976270291; called by muse, mutect2, varscan2
- AC026271.4 | n.38-10348G>A | Intron (SNP) | VAF 25/86 reads (29%) | called by muse, mutect2, varscan2
- ADAMTS18 | c.-253A>T | 5'UTR (SNP) | VAF 47/116 reads (41%) | called by muse, mutect2, varscan2
- ADGRL2 | c.398-1035G>T | Intron (SNP) | VAF 9/10 reads (90%) | called by muse, mutect2, varscan2
- ANKRD33 | c.263-224C>A | Intron (SNP) | VAF 5/35 reads (14%) | called by muse, varscan2
- BAALC | chr8:103229247 T>C | 3'Flank (SNP) | VAF 8/92 reads (9%) | called by muse, mutect2
- BEST3 | c.482-4702G>T | Intron (SNP) | VAF 9/87 reads (10%) | called by muse, mutect2, varscan2
- BNIP2 | c.*4137_*4141del | 3'UTR (DEL) | VAF 19/48 reads (40%) | called by mutect2, pindel, varscan2
- BTN3A1 | c.1019-609G>C | Intron (SNP) | VAF 58/153 reads (38%) | called by muse, mutect2, varscan2
- CAMK4 | c.*9125T>C | 3'UTR (SNP) | VAF 49/125 reads (39%) | called by muse, mutect2, varscan2
- CDH23 | c.3369+517G>A | Intron (SNP) | VAF 53/94 reads (56%) | called by muse, mutect2, varscan2
- CDK5R1 | c.*236T>C | 3'UTR (SNP) | VAF 17/29 reads (59%) | called by muse, mutect2, varscan2
- CDKN2AIP | c.*397T>A | 3'UTR (SNP) | VAF 32/102 reads (31%) | called by muse, mutect2, varscan2
- CFLAR | c.524-1338_524-1335del | Intron (DEL) | VAF 43/180 reads (24%) | called by mutect2, pindel, varscan2
- COL4A4 | c.*1244G>A | 3'UTR (SNP) | VAF 5/55 reads (9%) | called by muse, mutect2
- DCP2 | c.*3859G>T | 3'UTR (SNP) | VAF 22/51 reads (43%) | called by mutect2, varscan2
- DLGAP2 | c.*2401A>T | 3'UTR (SNP) | VAF 6/64 reads (9%) | catalogued as rs1424561064; called by muse, mutect2
- EPRS1 | c.3373+145A>C | Intron (SNP) | VAF 10/34 reads (29%) | called by muse, mutect2
- EPRS1 | c.3373+144C>G | Intron (SNP) | VAF 10/34 reads (29%) | called by muse, mutect2, varscan2
- EVPLL | c.672+30G>A | Intron (SNP) | VAF 10/16 reads (63%) | called by muse, mutect2, varscan2
- FARP2 | c.1893+1744A>G | Intron (SNP) | VAF 65/165 reads (39%) | called by muse, mutect2, varscan2
- FBXL15 | c.-615C>T | 5'UTR (SNP) | VAF 22/126 reads (17%) | called by muse, mutect2, varscan2
- GABRB3 | c.*2503G>T | 3'UTR (SNP) | VAF 7/17 reads (41%) | called by muse, mutect2, varscan2
- KLHL29 | c.940+37C>T | Intron (SNP) | VAF 36/100 reads (36%) | catalogued as rs1265178024; called by muse, mutect2, varscan2
- LHX9 | c.*3901_*3904del | 3'UTR (DEL) | VAF 30/94 reads (32%) | catalogued as rs1215070194; called by mutect2, pindel, varscan2
- MCTP1 | c.2436+504A>G | Intron (SNP) | VAF 23/48 reads (48%) | called by muse, mutect2, varscan2
- MN1 | c.*1148C>A | 3'UTR (SNP) | VAF 17/55 reads (31%) | called by muse, mutect2, varscan2
- MYO3A | c.*112A>G | 3'UTR (SNP) | VAF 20/76 reads (26%) | called by muse, mutect2, varscan2
- MYO9A | c.*584A>T | 3'UTR (SNP) | VAF 7/27 reads (26%) | called by muse, varscan2
- NDUFAF6 | c.420+744T>G | Intron (SNP) | VAF 14/36 reads (39%) | called by mutect2, varscan2
- NEGR1 | c.*444del | 3'UTR (DEL) | VAF 37/70 reads (53%) | catalogued as rs561597048; called by mutect2, pindel, varscan2
- NFATC2 | c.*4011T>A | 3'UTR (SNP) | VAF 13/40 reads (33%) | called by muse, mutect2, varscan2
- OR10AG1 | c.-6A>T | 5'UTR (SNP) | VAF 16/133 reads (12%) | called by muse, mutect2, varscan2
- PANX3 | c.*11A>T | 3'UTR (SNP) | VAF 64/190 reads (34%) | called by muse, mutect2, varscan2
- PAX6 | c.141+336A>C | Intron (SNP) | VAF 21/51 reads (41%) | called by muse, mutect2, varscan2
- PAX9 | c.*1100C>T | 3'UTR (SNP) | VAF 31/77 reads (40%) | called by muse, mutect2, varscan2
- PILRB | c.-217-430A>C | Intron (SNP) | VAF 6/23 reads (26%) | called by muse, mutect2, varscan2
- PYGO1 | c.*91del | 3'UTR (DEL) | VAF 56/157 reads (36%) | called by mutect2, pindel, varscan2
- RALA | c.*566T>C | 3'UTR (SNP) | VAF 5/47 reads (11%) | called by mutect2, varscan2
- RERGL | c.-184A>C | 5'UTR (SNP) | VAF 26/348 reads (7%) | called by muse, mutect2
- RPRM | c.*109A>T | 3'UTR (SNP) | VAF 13/67 reads (19%) | called by muse, mutect2, varscan2
- S1PR2 | c.-43+722C>A | Intron (SNP) | VAF 48/91 reads (53%) | catalogued as COSV73912781; called by muse, mutect2, varscan2
- SEMA3A | c.*561C>A | 3'UTR (SNP) | VAF 17/47 reads (36%) | called by muse, varscan2
- SEPTIN7 | c.*157_*158del | 3'UTR (DEL) | VAF 15/128 reads (12%) | called by pindel, varscan2
- SLCO1B3 | c.*301A>T | 3'UTR (SNP) | VAF 32/96 reads (33%) | called by muse, mutect2, varscan2
- SNORD115-9 | chr15:25182370 G>A | 5'Flank (SNP) | VAF 36/68 reads (53%) | called by muse, mutect2, varscan2
- ST8SIA4 | c.503+944T>A | Intron (SNP) | VAF 9/28 reads (32%) | catalogued as rs1024619675; called by muse, mutect2, varscan2
- STX5 | c.*422T>G | 3'UTR (SNP) | VAF 17/37 reads (46%) | called by muse, mutect2, varscan2
- SVIL2P | n.805A>T | RNA (SNP) | VAF 33/53 reads (62%) | called by muse, mutect2, varscan2
- TBC1D15 | c.31-10606T>G | Intron (SNP) | VAF 42/129 reads (33%) | called by muse, mutect2, varscan2
- TDRP | c.*738G>A | 3'UTR (SNP) | VAF 40/93 reads (43%) | called by muse, mutect2, varscan2
- TFAM | c.*3145C>T | 3'UTR (SNP) | VAF 11/36 reads (31%) | catalogued as rs976322956; called by muse, mutect2, varscan2
- TPRG1 | c.633+4968T>C | Intron (SNP) | VAF 88/185 reads (48%) | catalogued as rs912356466; called by muse, mutect2, varscan2
- TUBB8 | c.166+11C>T | Intron (SNP) | VAF 9/23 reads (39%) | catalogued as rs368865511; called by muse, mutect2, varscan2
- WASL | c.*2497dup | 3'UTR (INS) | VAF 19/49 reads (39%) | catalogued as rs1219538841; called by mutect2, varscan2
- WT1 | chr11:32438793 T>C | 5'Flank (SNP) | VAF 26/68 reads (38%) | called by muse, mutect2, varscan2
- ZDHHC21 | c.*1672T>A | 3'UTR (SNP) | VAF 13/58 reads (22%) | called by muse, mutect2, varscan2
